Somatic mutation profile of tumor specimen BLGSP-71-06-00097-01A (aliquot BLGSP-71-06-00097-01A-01D-A690-33) from CGCI case BLGSP-71-06-00097, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt-like lymphoma; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.8 years (2,475 days).
Specimen BLGSP-71-06-00097-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb78159d-2d9f-4c9c-a5b6-caacab3ed720.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00097-12A (Buccal Cell Normal), aliquot BLGSP-71-06-00097-12A-01W-A690-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2faade8-0bf8-4071-8e49-2f0cb2adf490

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 4, 3'UTR 2, 5'UTR 2, 5'Flank 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD8 | c.4131G>A p.W1377* (on ENST00000646647 / NM_001170629.2; = p.W1098* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 200/418 reads (48%) | catalogued as rs1555314582; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.577C>G p.H193D | Missense Mutation (SNP) | VAF 51/120 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H1-5 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.238); catalogued as rs1210490306; called by muse, mutect2, varscan2
- MYC | c.187C>G p.P63A (on ENST00000377970; = p.P78A on NM_002467.6) | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52371402, COSV52372418, COSV99418908; called by muse, mutect2, varscan2
- TAS2R30 | c.5T>C p.I2T | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as rs1441990681; called by muse, mutect2, varscan2
- EIF4A1 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- KMT2D | c.7424dup p.E2476* | Frame Shift Ins (INS) | VAF 12/23 reads (52%) | called by mutect2, pindel, varscan2
- MYC | c.539A>G p.D180G (on ENST00000377970; = p.D195G on NM_002467.6) | Missense Mutation (SNP) | VAF 91/198 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AC072022.2 | c.*458T>A | 3'UTR (SNP) | VAF 127/322 reads (39%) | called by muse, varscan2
- AC072022.2 | c.*547T>A | 3'UTR (SNP) | VAF 131/330 reads (40%) | called by muse, varscan2
- BACH2 | c.-446+969C>T | Intron (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- CXCR4 | c.15+485G>T | Intron (SNP) | VAF 73/201 reads (36%) | catalogued as COSV54016636; called by muse, mutect2, varscan2
- MYC | chr8:127735883 del TCC | 5'Flank (DEL) | VAF 25/51 reads (49%) | called by mutect2, pindel, varscan2
- MYC | c.-180C>T | 5'UTR (SNP) | VAF 50/112 reads (45%) | catalogued as COSV104388036, COSV104388052, COSV104388259; called by muse, mutect2, varscan2
- MYC | c.-27G>A | 5'UTR (SNP) | VAF 93/180 reads (52%) | catalogued as COSV104388510, COSV52367188, COSV52382270; called by muse, mutect2, varscan2
- TMSB4X | c.-17+229T>A | Intron (SNP) | VAF 148/189 reads (78%) | called by muse, mutect2, varscan2
- TP53 | c.993+281T>C | Intron (SNP) | VAF 163/480 reads (34%) | catalogued as COSV104370832; called by muse, mutect2, varscan2
